Somatic mutation profile of tumor specimen TCGA-CX-7219-01A (aliquot TCGA-CX-7219-01A-11D-2012-08) from TCGA case TCGA-CX-7219, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 47.2 years (17,222 days).
Specimen TCGA-CX-7219-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 843cc6d6-9c1e-4245-8f50-ccae38b56016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CX-7219-10A (Blood Derived Normal), aliquot TCGA-CX-7219-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39cb069d-3b1e-4b9d-80f1-3f3083325218

The open-access MAF lists 121 somatic variants for this specimen: 91 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 29, Nonsense Mutation 10, Frame Shift Del 3, Frame Shift Ins 2, Intron 1, Translation Start Site 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 22/41 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs483352697, CM984587, COSV52667931, COSV52674826, COSV52678297; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV100686245; called by muse, varscan2
- ADSS1 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209595501, COSV100272205; called by muse, mutect2, varscan2
- AFF1 | c.343T>C p.S115P | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100320376; called by muse, mutect2, varscan2
- AHNAK2 | c.15259C>T p.L5087F | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV60920058; called by muse, mutect2, varscan2
- AHNAK2 | c.11594G>T p.R3865L | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs377500233, COSV60906604; called by muse, mutect2, varscan2
- APBA1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV99595806; called by muse, mutect2, varscan2
- ASCC3 | c.5020C>T p.R1674C | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112466876, COSV100976363; called by muse, mutect2, varscan2
- ATM | c.8989G>A p.D2997N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99588976; called by muse, mutect2, varscan2
- BMT2 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs1249413542, COSV99774526; called by muse, mutect2
- BRSK2 | c.1607T>C p.V536A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV100372597; called by muse, mutect2, varscan2
- CA1 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV99810097; called by muse, mutect2, varscan2
- CAP1 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs765357509, COSV61224296, COSV61224571; called by muse, mutect2, varscan2
- CASKIN1 | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100623956; called by muse, mutect2, varscan2
- CCDC144A | c.1351A>T p.T451S | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.092); catalogued as rs958946252, COSV100138473; called by muse, mutect2, varscan2
- CCN4 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.458); catalogued as rs760043627, COSV51530809; called by muse, mutect2, varscan2
- CCNB1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1265958466, COSV99841257; called by muse, mutect2, varscan2
- CMTM1 | c.167T>C p.I56T (on ENST00000457188 / NM_181269.3; = p.I173T on NM_052999.4) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99862552; called by muse, mutect2, varscan2
- CNGA2 | c.1395G>C p.E465D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100323555, COSV61704068; called by muse, mutect2, varscan2
- CS | c.645G>C p.K215N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.184); catalogued as COSV100673201; called by muse, mutect2, varscan2
- CXorf56 | c.610G>C p.D204H (on ENST00000536133 / NM_001170570.2; = p.D218H on NM_022101.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100233368; called by muse, varscan2
- DDC | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 43/186 reads (23%) | catalogued as COSV100779199; called by muse, mutect2, varscan2
- DDX59 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494493; called by muse, mutect2, varscan2
- DIDO1 | c.4618C>T p.Q1540* | Nonsense Mutation (SNP) | VAF 51/110 reads (46%) | catalogued as COSV56630093; called by muse, mutect2, varscan2
- DIDO1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99825401; called by muse, mutect2, varscan2
- DIP2B | c.1461G>A p.W487* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99998264; called by muse, mutect2, varscan2
- DOP1A | c.1835G>T p.R612L | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV52708954, COSV99381549; called by muse, mutect2, varscan2
- DPYS | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs148513732, COSV100679476; called by muse, mutect2, varscan2
- EIF4G1 | c.3022G>T p.E1008* (on ENST00000346169 / NM_198241.3; = p.E813* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 48/171 reads (28%) | catalogued as COSV100071667; called by muse, mutect2, varscan2
- EIF4G1 | c.3751G>C p.E1251Q (on ENST00000346169 / NM_198241.3; = p.E1056Q on NM_004953.5) | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100071669; called by muse, mutect2, varscan2
- ENPEP | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); catalogued as rs1479797942, COSV54449676; called by muse, mutect2, varscan2
- EP300 | c.4028T>G p.F1343C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174786622, COSV99608107; called by muse, mutect2, varscan2
- ERC2 | c.215C>A p.S72* | Nonsense Mutation (SNP) | VAF 51/123 reads (41%) | catalogued as COSV55618845, COSV99883113; called by muse, mutect2, varscan2
- FAM83E | c.1340G>C p.R447T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99572164; called by muse, mutect2, varscan2
- FERD3L | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.255); catalogued as rs1358709099, COSV99284850; called by muse, mutect2, varscan2
- GATAD2A | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs764942647, COSV53065995; called by muse, mutect2, varscan2
- GDPD5 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100409229; called by muse, mutect2, varscan2
- GPR176 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs373118560; called by muse, mutect2, varscan2
- HECW2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99646680; called by muse, mutect2, varscan2
- HELQ | c.2295G>A p.K765= | Splice Region (SNP) | VAF 13/45 reads (29%) | catalogued as rs757556391, COSV99787573, COSV99787837; called by muse, mutect2, varscan2
- IFT88 | c.1711T>G p.Y571D (on ENST00000319980 / NM_001318493.2; = p.Y562D on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV100179600; called by muse, mutect2, varscan2
- IKZF1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100498267; called by muse, varscan2
- KHDRBS2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV99832641; called by muse, mutect2, varscan2
- KLHL17 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100497950; called by mutect2, varscan2
- LAMB1 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740410, COSV99740733; called by muse, mutect2, varscan2
- LRP1 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.14); catalogued as rs767368732, COSV99675389; called by muse, mutect2
- MKRN3 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1328576078, COSV100091007; called by muse, mutect2, varscan2
- MOB3B | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV51789726, COSV99218368; called by muse, mutect2, varscan2
- NBEAL1 | c.7912G>C p.E2638Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101355442; called by muse, mutect2, varscan2
- NDUFB6 | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1313260774, COSV100598281; called by muse, mutect2, varscan2
- NDUFV1 | c.1346G>A p.R449Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs748986683, COSV59596034; called by muse, mutect2, varscan2
- NEFL | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99647936; called by muse, varscan2
- NINL | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1236451377, COSV54004168; called by muse, mutect2, varscan2
- NRROS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100145443; called by muse, mutect2, varscan2
- OR10AG1 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1404432863, COSV100400028; called by muse, mutect2
- OR2H2 | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100589586; called by muse, mutect2, varscan2
- PCDH15 | c.1255A>C p.N419H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1210776570, COSV100218532; called by muse, mutect2, varscan2
- PDCD11 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV100874282, COSV63933273; called by muse, mutect2, varscan2
- PDE1A | c.1568C>G p.A523G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100113765; called by muse, mutect2, varscan2
- PGD | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs764012709, COSV54620838; called by muse, mutect2, varscan2
- PHRF1 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99199707, COSV99199831; called by muse, mutect2, varscan2
- PLCB1 | c.1955C>A p.P652Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100570213; called by muse, mutect2, varscan2
- PLCL2 | c.3053C>T p.A1018V (on ENST00000615277 / NM_001144382.2; = p.A892V on NM_015184.5) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV101196644; called by muse, mutect2, varscan2
- POM121L12 | c.786del p.A263Pfs*138 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as COSV68694799; called by mutect2, pindel, varscan2
- PRG4 | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 25/146 reads (17%) | catalogued as COSV100798161; called by muse, varscan2
- PRRC2B | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369955852; called by muse, mutect2, varscan2
- PSMC4 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99338210; called by muse, varscan2
- PSMD10 | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs771411859, COSV99480651; called by muse, mutect2, varscan2
- PUS1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs587781135, COSV59035736; called by muse, mutect2, varscan2
- RAD51AP1 | c.521C>G p.S174C (on ENST00000228843 / NM_001130862.2; = p.S157C on NM_006479.5) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99961212; called by muse, mutect2, varscan2
- RXFP3 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100347239, COSV100347459; called by muse, mutect2, varscan2
- SEC24A | c.2113A>G p.I705V | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as COSV100524423; called by muse, mutect2, varscan2
- SFSWAP | c.1453A>G p.R485G | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99905952; called by muse, mutect2, varscan2
- SLC5A7 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV99886519; called by muse, mutect2, varscan2
- SMARCC1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99592602; called by muse, mutect2, varscan2
- SPP1 | c.844G>T p.E282* (on ENST00000395080 / NM_001040058.2; = p.E268* on NM_000582.2) | Nonsense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV99420984; called by muse, mutect2
- TBX21 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); catalogued as rs746185082, COSV99455958; called by muse, mutect2, varscan2
- TCIRG1 | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99693266; called by muse, mutect2, varscan2
- TMEM252 | c.89G>C p.W30S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101051109; called by muse, mutect2, varscan2
- TRIM37 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99031714; called by muse, mutect2, varscan2
- UBE4B | c.2825A>T p.N942I (on ENST00000343090 / NM_001105562.3; = p.N813I on NM_006048.5) | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as COSV99476215; called by muse, mutect2, varscan2
- VPS13B | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV62018266, COSV62019968; called by muse, mutect2, varscan2
- YEATS2 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV100527687; called by muse, mutect2, varscan2
- ZNF132 | c.2003C>G p.S668C | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as COSV99571073; called by muse, mutect2
- ZNF136 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1256472126, COSV100677936; called by muse, mutect2, varscan2
- ACSS1 | c.172_200del p.Y58Gfs*67 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel
- ARSK | c.238_256+4del p.X80_splice | Splice Site (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- ASXL3 | c.2625dup p.V876Sfs*13 | Frame Shift Ins (INS) | VAF 30/62 reads (48%) | called by mutect2, varscan2
- FCF1 | c.420T>A p.Y140* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2
- KMT2E | c.4012del p.C1338Vfs*17 | Frame Shift Del (DEL) | VAF 48/160 reads (30%) | called by mutect2, pindel, varscan2
- PSIP1 | c.1128dup p.D378Gfs*2 | Frame Shift Ins (INS) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- ANO2 | c.1638C>T p.F546= (on ENST00000356134 / NM_001278597.3; = p.F550= on NM_001278596.3) | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs752551509, COSV100500424; called by muse, mutect2, varscan2
- ARHGEF28 | c.4599C>T p.H1533= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1258350405, COSV55252561; called by muse, mutect2, varscan2
- CLSTN2 | c.1494C>A p.G498= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs185070184, COSV101515430, COSV101515637; called by muse, varscan2
- DCUN1D3 | c.498C>T p.F166= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV100176789; called by muse, mutect2, varscan2
- DMBT1 | c.3315T>C p.T1105= (on ENST00000338354 / NM_001377530.1; = p.T606= on NM_004406.3) | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100352648; called by muse, mutect2, varscan2
- ERAP1 | c.1818C>T p.G606= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV99700825; called by muse, mutect2, varscan2
- FRYL | c.231C>T p.T77= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs377561266; called by muse, mutect2, varscan2
- H3C3 | c.36C>G p.T12= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs754517911, COSV100778274, COSV63551002; called by muse, mutect2, varscan2
- HRG | c.732C>T p.F244= | Silent (SNP) | VAF 30/281 reads (11%) | catalogued as rs151028119; called by muse, mutect2, varscan2
- HSPA5 | c.129C>G p.G43= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as rs368045596, COSV100189867; called by muse, mutect2
- IPO7 | c.541C>T p.L181= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV101121809; called by muse, mutect2, varscan2
- IRAK1BP1 | c.627A>G p.K209= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100884856; called by muse, mutect2, varscan2
- KIF26B | c.2025C>T p.D675= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs376804048; called by muse, varscan2
- MAST3 | c.150G>A p.S50= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs371510297; called by muse, mutect2, varscan2
- MELK | c.514C>T p.L172= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV99974462; called by muse, mutect2, varscan2
- MRGPRX3 | c.822C>T p.F274= | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as rs896228386, COSV66933213; called by muse, mutect2, varscan2
- ODF2 | c.69C>T p.L23= (on ENST00000434106 / NM_153433.2; = p.L67= on NM_153432.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100654521, COSV100655019; called by muse, mutect2, varscan2
- PIGW | c.552G>A p.E184= | Silent (SNP) | VAF 37/194 reads (19%) | called by muse, mutect2, varscan2
- PTPRC | c.3190C>T p.L1064= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs1558039602, COSV100722421; called by muse, mutect2, varscan2
- SDF4 | c.1014C>T p.F338= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99767519; called by muse, varscan2
- SEC23A | c.153A>G p.L51= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100305269; called by muse, mutect2, varscan2
- SKP2 | c.123G>C p.L41= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99682751; called by muse, mutect2, varscan2
- SLCO1C1 | c.1698C>T p.S566= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV99858846; called by muse, mutect2, varscan2
- SPHKAP | c.891G>A p.Q297= | Silent (SNP) | VAF 62/236 reads (26%) | catalogued as COSV100763976; called by muse, mutect2, varscan2
- SURF4 | c.174C>T p.T58= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100915188; called by muse, mutect2, varscan2
- SZT2 | c.8736G>A p.L2912= (on ENST00000634258 / NM_001365999.1; = p.L2855= on NM_015284.4) | Silent (SNP) | VAF 48/219 reads (22%) | catalogued as COSV100987049; called by muse, mutect2, varscan2
- TET1 | c.1599C>T p.L533= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs751740255, COSV101017895; called by muse, varscan2
- TTN | c.2640G>A p.Q880= (on ENST00000591111; = p.Q834= on NM_003319.4) | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV100604264; called by muse, mutect2, varscan2
- WDFY3 | c.4047A>G p.K1349= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV99882952; called by muse, mutect2, varscan2
- SDF4 | c.892-51G>A | Intron (SNP) | VAF 24/66 reads (36%) | catalogued as rs144630443; called by muse, mutect2, varscan2
